Gene-level copy-number profile of tumor specimen TCGA-44-3917-01A from TCGA case TCGA-44-3917, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 33.3 years (12,179 days).
Specimen TCGA-44-3917-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.a4f3c167-3875-4cef-b2ab-1bbdc10c5794.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-3917-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 394 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/145aaa8b-169b-4b88-b31b-cc530d2cd97f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 595; copy number 1: 2,215; copy number 2: 26,582; copy number 3: 17,323; copy number 4: 6,649; copy number 5: 2,877; copy number 6: 3,062; copy number 7: 234; copy number 8: 324; copy number 9: 194; copy number 10: 155; copy number 12: 4; copy number 14: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-3917-01A-01D-A273-01): tumor purity 0.38, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,297,264–90,235,370, 46 genes: IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, AC006453.3, LSP1P5, 5S_rRNA, AC006453.1, AC006453.2, AC006453.4, IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr17:41,265,339–41,271,835, 2 genes (within-gene range 0–3): KRTAP9-6, KRTAP9-11P.
- chr20:15,619,494–15,619,819, 1 gene: ENSAP1.
- chr20:16,857,962–17,735,871, 17 genes: AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2.
- chr21:14,108,813–14,658,821, 7 genes (within-gene range 0–1): LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,865 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–5,862,741, 226 genes, copy number 5 (broad region; genes not listed).
- chr1:43,933,320–44,844,082, 48 genes, copy number 6: ARTN, AL357079.1, AL357079.3, IPO13, AL357079.2, DPH2, ATP6V0B, B4GALT2, CCDC24, SLC6A9, AL139220.2, AL139220.1, KRT8P47, RN7SL479P, KLF17, AL356653.1, KLF18, AL359839.1, Y_RNA, OOSP1P1, AL035417.1, AL035417.2, DMAP1, ERI3, ERI3-IT1, RNU6-369P, RNF220, MIR5584, TMEM53, ARMH1, RNU5F-1, RNU5D-1, KIF2C, AL592166.1, RPS8, SNORD55, SNORD46, SNORD38A, SNORD38B, SNORD38B, RPS15AP11, BEST4, PLK3, TCTEX1D4, BTBD19, PTCH2, RNU5E-6P, AL136380.1.
- chr1:155,277,463–166,682,196, 389 genes, copy number 6–10 (broad region; genes not listed).
- chr1:172,210,711–226,493,489, 973 genes, copy number 6 (broad region; genes not listed).
- chr1:227,234,269–228,687,826, 84 genes, copy number 6 (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 14 (within-gene range 3–14): AC244205.1.
- chr2:88,857,161–89,275,787, 41 genes, copy number 6–14: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34.
- chr2:172,137,345–172,370,401, 3 genes, copy number 5 (within-gene range 3–5): AC104088.1, AC104088.3, AC104088.2.
- chr3:71,541,970–78,294,731, 97 genes, copy number 5–7 (broad region; genes not listed).
- chr3:78,597,239–89,048,434, 69 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr4:143,996,104–144,019,380, 2 genes, copy number 5: GYPB, AC093890.2.
- chr6:57,314,805–69,389,506, 76 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr6:69,705,287–69,706,160, 1 gene, copy number 5: NPM1P37.
- chr7:70,972–39,493,095, 698 genes, copy number 5 (within-gene range 4–12) (broad region; genes not listed).
- chr7:39,404,590–75,994,656, 732 genes, copy number 5–12 (broad region; genes not listed).
- chr7:77,793,728–108,456,717, 547 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:110,662,644–111,562,517, 1 gene, copy number 5 (within-gene range 3–5): IMMP2L.
- chr7:111,091,006–124,790,689, 175 genes, copy number 5 (broad region; genes not listed).
- chr8:18,989,279–19,000,952, 1 gene, copy number 7 (within-gene range 2–7): AC009884.1.
- chr8:38,510,834–38,704,855, 4 genes, copy number 5: C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6 (broad region; genes not listed).
- chr9:36,779,475–36,830,456, 2 genes, copy number 10 (within-gene range 2–10): AL450267.2, MIR4475.
- chr11:32,602,246–36,697,867, 84 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr11:86,945,679–87,021,909, 2 genes, copy number 5 (within-gene range 3–5): FZD4, FZD4-DT.
- chr12:3,124,777–3,125,063, 1 gene, copy number 8: Metazoa_SRP.
- chr12:8,940,361–8,949,761, 1 gene, copy number 6: M6PR.
- chr12:115,299,588–115,332,566, 3 genes, copy number 5 (within-gene range 3–5): AC078880.3, AC078880.4, AC078880.5.
- chr13:73,100,575–73,113,018, 2 genes, copy number 5: FABP5P1, RNU6-66P.
- chr14:34,740,336–49,077,505, 179 genes, copy number 9 (broad region; genes not listed).
- chr14:105,764,503–106,461,055, 117 genes, copy number 10 (broad region; genes not listed).
- chr18:12,192,203–13,185,617, 34 genes, copy number 5–7: PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3, PSMG2, CEP76, AP005482.2, AP005482.1, LINC01882, Y_RNA, PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2.
- chr18:30,954,820–44,071,701, 153 genes, copy number 5–12 (broad region; genes not listed).
- chr18:67,375,133–80,247,514, 205 genes, copy number 5–6 (broad region; genes not listed).
- chr19:15,613,247–15,630,639, 2 genes, copy number 7: AC093072.1, CYP4F8.
- chr19:19,512,418–30,872,507, 289 genes, copy number 5 (broad region; genes not listed).
- chr20:16,272,104–16,684,404, 6 genes, copy number 6: KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1.
- chr20:19,208,652–22,471,557, 57 genes, copy number 5–7: AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1.
- chr20:24,679,547–25,611,223, 26 genes, copy number 6: AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P.

Autosomal genes at a single copy (total copy number 1): 100. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
